Somatic mutation profile of tumor specimen 1105264 (aliquot 7316UP-1766-1105264) from CPTAC case C383391, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Astrocytoma, NOS; Tissue or organ of origin: Temporal lobe; Tumor grade: G3.
Specimen 1105264: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a6be4e88-e762-4e48-9b61-c0524c24e0b5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 1105272 (Blood Derived Normal), aliquot 7316UP-1108-1105272; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c8b20645-5e03-4d35-97da-1ce426d5760d

The open-access MAF lists 60 somatic variants for this specimen: 35 protein-altering or splice-affecting, 22 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, Silent 22, 5'UTR 2, Nonsense Mutation 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.1787C>T p.P596L | Missense Mutation (SNP) | VAF 115/3756 reads (3%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1477025000, COSV51779162, COSV51807036; called by muse, mutect2
- ARHGAP44 | c.104G>A p.R35H | Missense Mutation (SNP) | VAF 29/193 reads (15%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as rs367607261; called by muse, mutect2, varscan2
- BMP10 | c.712C>T p.R238W | Missense Mutation (SNP) | VAF 22/190 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.606); catalogued as rs144469983; called by muse, mutect2, varscan2
- CAMSAP3 | c.3101G>A p.R1034H | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.764); catalogued as rs888893073, COSV50331293; called by muse, mutect2
- CHAT | c.1037G>A p.R346H | Missense Mutation (SNP) | VAF 51/382 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.011); catalogued as rs779668516, COSV60334873; called by muse, mutect2, varscan2
- COL6A5 | c.2644C>T p.R882W | Missense Mutation (SNP) | VAF 29/223 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs374168010; called by muse, mutect2, varscan2
- DDX60 | c.2360C>T p.T787M | Missense Mutation (SNP) | VAF 22/244 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1489149518; called by muse, mutect2
- FAT1 | c.7556G>A p.G2519E | Missense Mutation (SNP) | VAF 16/259 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs550477464; called by muse, mutect2
- FRMPD4 | c.1955C>T p.S652F | Missense Mutation (SNP) | VAF 19/110 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV66223539; called by muse, mutect2, varscan2
- KRT1 | c.1894G>A p.V632M | Missense Mutation (SNP) | VAF 42/506 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.44); catalogued as rs532003323, COSV52868090; called by muse, mutect2
- KRTAP4-6 | c.185G>A p.R62H | Missense Mutation (SNP) | VAF 70/576 reads (12%) | SIFT tolerated (0.13); catalogued as rs763253803, COSV61980902; called by muse, varscan2
- MROH9 | c.2267C>T p.S756L | Missense Mutation (SNP) | VAF 16/193 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.451); catalogued as rs889208046, COSV63015141; called by muse, mutect2
- MYOD1 | c.308G>A p.R103H | Missense Mutation (SNP) | VAF 19/175 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51456293; called by muse, mutect2, varscan2
- OBSL1 | c.4396G>A p.V1466M | Missense Mutation (SNP) | VAF 8/107 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.144); catalogued as rs1408776700, COSV54703126; ClinVar: uncertain significance; called by muse, mutect2
- PNKD | c.454C>T p.R152W | Missense Mutation (SNP) | VAF 15/222 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.417); catalogued as rs756863425, COSV51231403; ClinVar: uncertain significance; called by muse, mutect2
- PTH2R | c.448G>A p.V150I | Missense Mutation (SNP) | VAF 33/325 reads (10%) | SIFT tolerated (0.36); PolyPhen benign (0.05); catalogued as rs753279962, COSV55915312; called by muse, mutect2, varscan2
- RBFOX1 | c.830G>A p.R277H | Missense Mutation (SNP) | VAF 19/176 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs376377058; called by muse, mutect2, varscan2
- RELN | c.9904G>A p.A3302T | Missense Mutation (SNP) | VAF 62/702 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.266); catalogued as rs776769644, COSV59040921; called by muse, mutect2
- RELN | c.2260C>T p.R754W | Missense Mutation (SNP) | VAF 59/551 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs759711654, COSV59024775; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RPL5 | c.272G>A p.G91D | Missense Mutation (SNP) | VAF 26/421 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV100240435; called by muse, mutect2
- TUBA3C | c.389C>T p.T130M | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.695); catalogued as rs923497577, COSV67139620; called by muse, varscan2
- VAV2 | c.1351G>A p.E451K (on ENST00000371850 / NM_001134398.2; = p.E446K on NM_003371.4) | Missense Mutation (SNP) | VAF 11/109 reads (10%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.772); catalogued as rs755369467; called by muse, mutect2, varscan2
- XKR3 | c.568C>T p.R190* | Nonsense Mutation (SNP) | VAF 22/236 reads (9%) | catalogued as rs562118958; called by muse, mutect2
- CD96 | c.1480A>G p.T494A (on ENST00000283285 / NM_198196.3; = p.T478A on NM_005816.5) | Missense Mutation (SNP) | VAF 65/524 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.35); called by muse, mutect2, varscan2
- CLEC4G | c.593C>T p.A198V | Missense Mutation (SNP) | VAF 22/184 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- CREBBP | c.3197G>A p.S1066N | Missense Mutation (SNP) | VAF 40/317 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- CRYBG1 | c.3650C>A p.P1217Q | Missense Mutation (SNP) | VAF 34/342 reads (10%) | SIFT tolerated (0.41); PolyPhen benign (0.068); called by muse, mutect2
- DLAT | c.1132A>C p.T378P | Missense Mutation (SNP) | VAF 15/380 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2
- DLC1 | c.776A>T p.D259V | Missense Mutation (SNP) | VAF 16/141 reads (11%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); called by mutect2, varscan2
- EEFSEC | c.1681A>G p.R561G | Missense Mutation (SNP) | VAF 14/287 reads (5%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2
- GOLGA7 | c.344C>T p.P115L | Missense Mutation (SNP) | VAF 9/140 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.585); called by muse, mutect2
- MYH13 | c.2028T>A p.C676* | Nonsense Mutation (SNP) | VAF 16/221 reads (7%) | called by muse, mutect2
- NOBOX | c.88C>T p.P30S | Missense Mutation (SNP) | VAF 32/312 reads (10%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.017); called by muse, mutect2
- THADA | c.2371C>A p.L791I | Missense Mutation (SNP) | VAF 13/137 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.093); called by muse, mutect2
- TMEM132C | c.2708A>G p.K903R | Missense Mutation (SNP) | VAF 23/215 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ADAM29 | c.612C>T p.V204= | Silent (SNP) | VAF 8/114 reads (7%) | catalogued as rs114696296, COSV63668865; called by muse, mutect2
- ARID1A | c.6057C>T p.H2019= | Silent (SNP) | VAF 28/336 reads (8%) | called by muse, mutect2
- ARPC4 | c.114G>A p.V38= | Silent (SNP) | VAF 13/144 reads (9%) | catalogued as rs1482592313; called by muse, mutect2
- CHRM2 | c.117C>T p.I39= | Silent (SNP) | VAF 40/310 reads (13%) | catalogued as rs755854009, COSV57773475; called by muse, mutect2, varscan2
- CLSTN2 | c.2004C>T p.F668= | Silent (SNP) | VAF 24/236 reads (10%) | catalogued as rs778778245, COSV71720462; called by muse, mutect2, varscan2
- CYP4A11 | c.180C>T p.F60= | Silent (SNP) | VAF 14/130 reads (11%) | catalogued as rs763129685, COSV60222221; called by muse, mutect2, varscan2
- DLC1 | c.2967G>T p.G989= (on ENST00000276297 / NM_001348081.2; = p.G552= on NM_006094.5) | Silent (SNP) | VAF 20/150 reads (13%) | catalogued as rs1563589459; called by muse, varscan2
- DLX3 | c.798G>A p.P266= | Silent (SNP) | VAF 30/371 reads (8%) | catalogued as rs569475772; ClinVar: uncertain significance; called by muse, mutect2
- DPYSL2 | c.645G>T p.L215= | Silent (SNP) | VAF 47/384 reads (12%) | called by muse, mutect2, varscan2
- MYH7 | c.4740C>T p.D1580= | Silent (SNP) | VAF 32/235 reads (14%) | catalogued as rs201469051, COSV62516883; called by muse, mutect2, varscan2
- NDRG4 | c.654G>A p.T218= (on ENST00000570248 / NM_001378344.1; = p.T250= on NM_020465.4 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 30/255 reads (12%) | catalogued as rs781381338, COSV99262394; called by muse, mutect2, varscan2
- OR2AK2 | c.99C>G p.T33= | Silent (SNP) | VAF 10/132 reads (8%) | catalogued as COSV63554593; called by muse, mutect2
- OR5AU1 | c.267G>A p.R89= | Silent (SNP) | VAF 38/412 reads (9%) | catalogued as rs779575360; called by muse, mutect2
- PRDM16 | c.2667G>A p.P889= | Silent (SNP) | VAF 12/155 reads (8%) | catalogued as rs774537766; ClinVar: likely benign; called by muse, mutect2
- SLC30A3 | c.933G>A p.S311= | Silent (SNP) | VAF 37/376 reads (10%) | catalogued as rs538009364, COSV99273777, COSV99273918; ClinVar: likely benign; called by muse, mutect2
- SLC7A14 | c.726G>A p.A242= | Silent (SNP) | VAF 36/264 reads (14%) | catalogued as rs752901596, COSV51580118; called by muse, mutect2, varscan2
- SV2C | c.1647A>G p.P549= | Silent (SNP) | VAF 23/149 reads (15%) | called by muse, mutect2, varscan2
- TANC1 | c.600C>T p.S200= | Silent (SNP) | VAF 40/506 reads (8%) | catalogued as rs1362556739; called by muse, mutect2
- TOP2A | c.927G>A p.Q309= | Silent (SNP) | VAF 15/104 reads (14%) | catalogued as rs1403734143; called by muse, mutect2, varscan2
- UNC13C | c.4164C>A p.V1388= | Silent (SNP) | VAF 23/232 reads (10%) | called by muse, mutect2, varscan2
- USH2A | c.6579C>T p.I2193= | Silent (SNP) | VAF 26/217 reads (12%) | catalogued as rs765566223; called by muse, mutect2, varscan2
- ZAN | c.4158C>T p.C1386= | Silent (SNP) | VAF 28/238 reads (12%) | catalogued as rs376999914; called by muse, mutect2, varscan2
- GABBR1 | c.476-60G>T | Intron (SNP) | VAF 62/401 reads (15%) | catalogued as rs1347490372; called by muse, mutect2, varscan2
- HYPK | c.-764C>T | 5'UTR (SNP) | VAF 44/470 reads (9%) | catalogued as rs756657635; called by muse, mutect2
- LILRA5 | c.-44T>A | 5'UTR (SNP) | VAF 23/208 reads (11%) | catalogued as rs1380637405; called by muse, mutect2, varscan2
